Somatic mutation profile of tumor specimen SM-JU32Q (aliquot 7316UP-587) from CPTAC case C289419, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU32Q: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18342df7-5545-4bda-a768-181389cb6e50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105213 (Blood Derived Normal), aliquot 7316UP-587-1105213; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06a59c38-b044-4140-ad6d-9e29bc92322a

The open-access MAF lists 68 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 16, Intron 6, 5'UTR 4, Frame Shift Del 3, RNA 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRF3 | c.1600G>A p.V534M (on ENST00000311519 / NM_001145168.1; = p.V335M on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs753721966; called by muse, mutect2, varscan2
- CACNA1C | c.4900C>T p.R1634C | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100221064; called by muse, mutect2, varscan2
- EGFLAM | c.2010C>A p.H670Q | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV59292831; called by muse, mutect2, varscan2
- FAM83B | c.2125A>T p.S709C | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60921674; called by muse, mutect2, varscan2
- FGD5 | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200418068, COSV53245646; called by muse, mutect2, varscan2
- GPR139 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs773441202, COSV58502871; called by muse, mutect2, varscan2
- MAGEB3 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 84/132 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV64397343; called by muse, mutect2, varscan2
- MED17 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV52599283; called by muse, mutect2, varscan2
- MYO1B | c.2977G>A p.V993M (on ENST00000304164; = p.V935M on NM_012223.5) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762023617, COSV58428035; called by muse, mutect2, varscan2
- OR51B6 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs917484033; called by muse, mutect2, varscan2
- OR51F2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs202173777, COSV59063723; called by muse, mutect2, varscan2
- PTEN | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64289424; called by muse, mutect2, varscan2
- RELN | c.2887G>A p.V963I | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as rs761991712, COSV58996805; called by muse, mutect2, varscan2
- SLC25A20 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 151/539 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs376860154; called by muse, mutect2, varscan2
- SSBP3 | c.853G>A p.A285T (on ENST00000371320 / NM_145716.4; = p.A265T on NM_018070.5) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs1018009964, COSV58890055; called by muse, mutect2, varscan2
- TEKT3 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 97/329 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763214298, COSV58629446; called by muse, mutect2, varscan2
- ZC3H13 | c.4712A>G p.N1571S (on ENST00000242848 / NM_001330565.2; = p.N1572S on NM_001076788.2 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs1374656138; called by muse, mutect2, varscan2
- ARHGAP25 | c.1392G>C p.E464D (on ENST00000409202 / NM_001007231.3; = p.E456D on NM_014882.3) | Missense Mutation (SNP) | VAF 77/308 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ARHGAP25 | c.1647G>C p.E549D (on ENST00000409202 / NM_001007231.3; = p.E541D on NM_014882.3) | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLEC1B | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- EIF4H | c.40A>G p.S14G | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM166C | c.572A>G p.K191R | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- HHIPL1 | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LAMA3 | c.9342del p.K3115Nfs*14 (on ENST00000313654 / NM_198129.4; = p.K1506Nfs*14 on NM_000227.6) | Frame Shift Del (DEL) | VAF 93/318 reads (29%) | called by mutect2, pindel, varscan2
- NEBL | c.1791_1794del p.E598Wfs*7 | Frame Shift Del (DEL) | VAF 52/200 reads (26%) | called by pindel, varscan2
- NFE2 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 119/454 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRK | c.633T>A p.S211R | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR4A16 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PDCD6 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCSH | c.1566A>C p.E522D | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRMT7 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RSBN1 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SH3BP5L | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAG2 | c.446_449del p.T149Kfs*33 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, pindel, varscan2
- TTN | c.76889A>T p.D25630V (on ENST00000591111; = p.D18206V on NM_003319.4) | Missense Mutation (SNP) | VAF 169/584 reads (29%) | PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TTN | c.51774C>G p.N17258K (on ENST00000591111; = p.N9834K on NM_003319.4) | Missense Mutation (SNP) | VAF 218/712 reads (31%) | PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZMYM6 | c.1379A>G p.D460G | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ATF7IP | c.2934T>C p.A978= | Silent (SNP) | VAF 36/188 reads (19%) | called by muse, mutect2, varscan2
- DENND2C | c.1299T>A p.T433= (on ENST00000393274 / NM_001256404.2; = p.T376= on NM_198459.4) | Silent (SNP) | VAF 42/167 reads (25%) | called by muse, mutect2, varscan2
- FCHO1 | c.285C>T p.L95= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as COSV99406523; called by muse, mutect2, varscan2
- FYB1 | c.705C>T p.S235= | Silent (SNP) | VAF 45/345 reads (13%) | catalogued as rs748439196, COSV60943251; called by muse, mutect2, varscan2
- HTR1E | c.435C>T p.T145= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1381760056, COSV59506510; called by muse, mutect2, varscan2
- KRTAP8-1 | c.45C>T p.Y15= | Silent (SNP) | VAF 25/147 reads (17%) | called by muse, mutect2, varscan2
- LCT | c.3135C>T p.Y1045= | Silent (SNP) | VAF 160/549 reads (29%) | catalogued as rs754582267, COSV51555493; called by muse, mutect2, varscan2
- METTL14 | c.1272C>G p.G424= | Silent (SNP) | VAF 70/236 reads (30%) | called by muse, mutect2, varscan2
- NUP153 | c.4254T>C p.G1418= | Silent (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- OR2Y1 | c.63G>A p.P21= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as rs749891000, COSV57137855; called by muse, mutect2, varscan2
- RICTOR | c.2589T>C p.Y863= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as rs1443605726; called by muse, mutect2, varscan2
- SLC25A44 | c.669C>T p.V223= | Silent (SNP) | VAF 81/244 reads (33%) | called by muse, mutect2, varscan2
- SLC6A13 | c.966C>T p.S322= | Silent (SNP) | VAF 55/205 reads (27%) | catalogued as rs149831603; called by muse, mutect2, varscan2
- SYN2 | c.282C>T p.A94= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as CD140011; called by muse, mutect2, varscan2
- TRAV22 | c.258G>A p.T86= | Silent (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- YME1L1 | c.2283T>A p.I761= (on ENST00000326799 / NM_139312.3; = p.I704= on NM_014263.4) | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV58761380; called by muse, mutect2, varscan2
- AC004080.3 | c.11-4437C>T | Intron (SNP) | VAF 108/439 reads (25%) | called by muse, varscan2
- AC021218.1 | n.991T>C | RNA (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1140C>T | Intron (SNP) | VAF 48/154 reads (31%) | called by muse, mutect2, varscan2
- COL2A1 | c.1942-45G>T | Intron (SNP) | VAF 105/359 reads (29%) | called by muse, mutect2, varscan2
- DPAGT1 | c.1161+30G>A | Intron (SNP) | VAF 118/464 reads (25%) | catalogued as rs777584035, COSV99597773; called by muse, mutect2, varscan2
- ERLIN2 | chr8:37736022 G>T | 5'Flank (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- GPAA1 | c.-66C>T | 5'UTR (SNP) | VAF 35/102 reads (34%) | catalogued as rs942261798; called by muse, mutect2, varscan2
- IL15 | c.-13G>A | 5'UTR (SNP) | VAF 6/43 reads (14%) | catalogued as rs753451417; called by muse, mutect2, varscan2
- PDCD6 | c.163+68T>C | Intron (SNP) | VAF 31/173 reads (18%) | called by muse, mutect2, varscan2
- PECR | c.*19C>T | 3'UTR (SNP) | VAF 83/294 reads (28%) | called by muse, mutect2, varscan2
- PIK3CD | c.1471-19G>C | Intron (SNP) | VAF 48/1974 reads (2%) | called by muse, mutect2
- RNF5P1 | n.52C>T | RNA (SNP) | VAF 60/202 reads (30%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.-38G>A | 5'UTR (SNP) | VAF 12/31 reads (39%) | catalogued as rs1248196134; called by muse, mutect2, varscan2
- SEC23A | c.-2C>T | 5'UTR (SNP) | VAF 50/147 reads (34%) | called by muse, mutect2, varscan2
